Somatic mutation profile of tumor specimen TCGA-E6-A8L9-01A (aliquot TCGA-E6-A8L9-01A-21D-A37N-09) from TCGA case TCGA-E6-A8L9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 61.1 years (22,333 days).
Specimen TCGA-E6-A8L9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d26f83c-8222-42fb-985f-6d21382def3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E6-A8L9-10A (Blood Derived Normal), aliquot TCGA-E6-A8L9-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd656206-ea5e-4259-85f9-b74cb7b43970

The open-access MAF lists 51 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 7, Splice Region 2, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 31/37 reads (84%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 18/20 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADH1C | c.566A>T p.K189M | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101565159; called by muse, mutect2, varscan2
- BANK1 | c.1094G>T p.C365F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100535901; called by muse, mutect2, varscan2
- CEP152 | c.3181C>A p.H1061N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.098); catalogued as COSV100358532; called by muse, mutect2
- CHD4 | c.2951T>G p.L984R (on ENST00000357008 / NM_001363606.2; = p.L997R on NM_001273.5) | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58895018; called by muse, mutect2, varscan2
- CLASRP | c.1847G>C p.R616P | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs763881125, COSV99673554; called by muse, mutect2, varscan2
- CLUH | c.1442G>C p.R481P (on ENST00000435359; = p.R519P on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/75 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101425637; called by muse, mutect2, varscan2
- DMD | c.9523G>A p.V3175M | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1332708845, COSV100626046, COSV58901549; called by muse, mutect2, varscan2
- DMD | c.8839G>C p.D2947H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100626049; called by muse, mutect2, varscan2
- ECPAS | c.4294A>T p.K1432* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99397587; called by muse, mutect2, varscan2
- EGFLAM | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs201885393, COSV100379863; called by muse, mutect2, varscan2
- EGR1 | c.432C>G p.N144K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV99525292; called by muse, mutect2, varscan2
- FAM83H | c.2563G>C p.E855Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.33); catalogued as rs782359952, COSV100567696; called by muse, mutect2, varscan2
- GPR55 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV101235721; called by muse, mutect2
- GPRASP1 | c.4154A>C p.N1385T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100850915; called by muse, mutect2, varscan2
- GRID2 | c.459T>A p.H153Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99937569; called by muse, mutect2, varscan2
- IL2RB | c.529A>C p.T177P | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99344682; called by muse, mutect2, varscan2
- ITPR1 | c.4613G>C p.R1538P (on ENST00000354582; = p.R1523P on NM_002222.7) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100229709; called by muse, mutect2, varscan2
- JMJD1C | c.4210G>A p.D1404N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs758453317, COSV100550161; called by muse, mutect2, varscan2
- KNDC1 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100463439; called by muse, mutect2, varscan2
- LGR6 | c.1058G>T p.R353M (on ENST00000367278 / NM_001017403.1; = p.R301M on NM_021636.3) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.657); catalogued as COSV99706104; called by muse, mutect2, varscan2
- MAML3 | c.1013A>T p.E338V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100504975, COSV59071390; called by muse, varscan2
- MSI2 | c.63-4C>G | Splice Region (SNP) | VAF 33/46 reads (72%) | catalogued as rs1481840818, COSV52362021, COSV99401726; called by muse, mutect2, varscan2
- NLGN3 | c.2149T>A p.S717T (on ENST00000358741 / NM_181303.2; = p.S697T on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100704560; called by muse, mutect2, varscan2
- OR5M8 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV100510556; called by muse, mutect2
- OR6C70 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100524336; called by muse, mutect2, varscan2
- PBDC1 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100972783; called by muse, mutect2, varscan2
- PDPR | c.1962G>A p.K654= | Splice Region (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99847809; called by muse, mutect2, varscan2
- PER1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs372164120; called by muse, mutect2, varscan2
- RBMX | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1179888238; called by muse, mutect2
- RCBTB2 | c.528G>C p.W176C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV60649541; called by muse, mutect2, varscan2
- RPA1 | c.1553T>C p.V518A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99627691; called by muse, mutect2
- RUNDC3B | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs563701368, COSV99712220; called by muse, mutect2, varscan2
- SDR16C5 | c.578G>C p.S193T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100373821; called by muse, mutect2, varscan2
- SORBS3 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53552018, COSV53553544; called by muse, mutect2
- TMEM132E | c.1724C>T p.T575M (on ENST00000321639; = p.T665M on NM_001304438.2) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1429069820, COSV58696451; called by muse, mutect2, varscan2
- UBE2D3 | c.44G>C p.R15P | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.242); catalogued as COSV100414849, COSV57662550; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99356771; called by muse, mutect2, varscan2
- FOXA2 | c.135del p.S45Rfs*14 (on ENST00000377115 / NM_153675.3; = p.S51Rfs*14 on NM_021784.5) | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- IGKV1-27 | c.7A>C p.M3L | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LGALS2 | c.112_118del p.G38Tfs*3 | Frame Shift Del (DEL) | VAF 33/152 reads (22%) | called by mutect2, pindel, varscan2
- C15orf39 | c.798C>A p.P266= | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as COSV100641196; called by muse, mutect2, varscan2
- CENPE | c.3801T>C p.N1267= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99477072, COSV99478009; called by muse, mutect2, varscan2
- GJB1 | c.657C>T p.R219= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100661237; called by muse, mutect2, varscan2
- GOLGA3 | c.1863C>A p.S621= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99202284; called by muse, mutect2, varscan2
- ICAM5 | c.831C>T p.L277= | Silent (SNP) | VAF 76/224 reads (34%) | catalogued as rs1483537761, COSV99703141; called by muse, mutect2, varscan2
- LRRK2 | c.1512G>A p.A504= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs200022961, COSV100109311; called by muse, mutect2, varscan2
- TLR7 | c.1713G>T p.L571= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV101027735; called by muse, mutect2, varscan2
- IDH3G | c.1080+54C>A | Intron (SNP) | VAF 9/45 reads (20%) | catalogued as COSV54207038, COSV99472961; called by muse, mutect2, varscan2
